Somatic mutation profile of tumor specimen ALCH-B2UF-TTP1-A (aliquot ALCH-B2UF-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2UF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.9 years (26,609 days).
Specimen ALCH-B2UF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02183057-227e-4433-9fca-5f38441df445.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UF-NB1-A (Blood Derived Normal), aliquot ALCH-B2UF-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e9ec2cb-32cb-40e1-8d4f-e55de1b22e02

The open-access MAF lists 120 somatic variants for this specimen: 86 protein-altering or splice-affecting, 19 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 19, Intron 7, Nonsense Mutation 5, RNA 4, Frame Shift Del 3, Frame Shift Ins 2, 5'Flank 2, 3'Flank 1, Splice Region 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 72/552 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AARD | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.019); catalogued as rs367780973, COSV65600327; called by muse, varscan2
- ADRA1A | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748400751; called by muse, mutect2, varscan2
- ANKMY2 | c.907G>T p.V303F | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100186992; called by muse, mutect2, varscan2
- ASXL3 | c.6577G>A p.A2193T | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as rs764681709; called by mutect2, varscan2
- BLM | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs202042636, COSV61927693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD247 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 65/806 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs752900365, COSV62977000; called by muse, mutect2
- CFAP92 | c.497G>T p.W166L | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99414702; called by muse, mutect2
- DIAPH1 | c.3704C>A p.S1235* | Nonsense Mutation (SNP) | VAF 25/500 reads (5%) | catalogued as COSV99338748; called by muse, mutect2
- FUZ | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1368662952; called by muse, mutect2
- GPD2 | c.1784C>G p.A595G | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs781425374; called by muse, mutect2
- IPO8 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV99805477, COSV99805518; called by muse, mutect2
- KCNH4 | c.1283C>A p.A428E | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV52916535; called by muse, mutect2, varscan2
- MAX | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 22/335 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as CM122944; called by muse, mutect2
- MUC16 | c.19573C>T p.P6525S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.02); catalogued as rs1448199562; called by muse, mutect2, varscan2
- NAV3 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.051); catalogued as rs771282817; called by muse, mutect2, varscan2
- NOS1 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980577637, COSV57609939, COSV57609984; called by muse, mutect2
- PCDH15 | c.3359G>C p.R1120P | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV57335422; called by muse, mutect2, varscan2
- PIEZO2 | c.2561C>A p.P854Q | Missense Mutation (SNP) | VAF 76/673 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs748442453, COSV57455519; called by muse, mutect2, varscan2
- PTPN12 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50372950; called by muse, mutect2
- PTPRD | c.1175G>T p.R392M | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV100645375; called by muse, mutect2
- SHANK3 | c.2692G>T p.A898S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV53183778; called by muse, varscan2
- SLC20A2 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755604221; called by muse, mutect2, varscan2
- SPINT1 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs914334103; called by muse, mutect2, varscan2
- STXBP2 | c.1697G>C p.G566A | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM125308; called by muse, mutect2, varscan2
- TECRL | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 49/548 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1394978564; called by muse, mutect2
- TLR7 | c.3010C>T p.R1004W | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs181600414; called by muse, mutect2
- ZFP57 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV65305828, COSV65306651; called by muse, mutect2, varscan2
- A2M | c.2575G>T p.A859S | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADAMTS20 | c.175C>A p.H59N | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ADGB | c.3926A>T p.E1309V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- AMFR | c.1352A>C p.Q451P | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ANKRD12 | c.5054A>G p.E1685G | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); called by muse, mutect2
- ANKRD36C | c.895G>C p.G299R | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- ARHGEF4 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 25/305 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- AVP | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C5AR2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCBE1 | c.483C>A p.C161* | Nonsense Mutation (SNP) | VAF 62/473 reads (13%) | called by muse, mutect2, varscan2
- CLCN3 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 23/433 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.173); called by muse, mutect2
- COL12A1 | c.3565G>T p.G1189W | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- COL12A1 | c.2169A>T p.K723N | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CSMD1 | c.4849C>A p.Q1617K (on ENST00000520002; = p.Q1616K on NM_033225.6) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2
- ERBIN | c.1209C>T p.S403= | Splice Region (SNP) | VAF 29/197 reads (15%) | called by muse, mutect2, varscan2
- FBLIM1 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- FIBCD1 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOSR2 | c.380_381del p.F127Yfs*58 (on ENST00000393456 / NM_001321134.1; = p.F192Yfs*58 on NM_004287.5) | Frame Shift Del (DEL) | VAF 64/559 reads (11%) | called by mutect2, pindel, varscan2
- GRHL2 | c.404A>T p.K135M | Missense Mutation (SNP) | VAF 70/561 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GRIA4 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 38/393 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2
- HASPIN | c.1257A>C p.E419D | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- HEPHL1 | c.585C>A p.D195E | Missense Mutation (SNP) | VAF 28/692 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- INSYN1 | c.799A>T p.S267C | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF21B | c.1263C>G p.F421L | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KIR2DL1 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 47/804 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2
- LRRC4C | c.1507A>T p.K503* | Nonsense Mutation (SNP) | VAF 38/322 reads (12%) | called by muse, mutect2, varscan2
- MEGF10 | c.1194G>C p.E398D | Missense Mutation (SNP) | VAF 20/377 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYCBP2 | c.13156G>T p.A4386S (on ENST00000357337; = p.A4424S on NM_015057.5) | Missense Mutation (SNP) | VAF 33/347 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- MYH11 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 54/521 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- NCOA4 | c.494A>C p.H165P | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NETO1 | c.374T>A p.V125D | Missense Mutation (SNP) | VAF 27/471 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- NLRP14 | c.2900A>T p.N967I | Missense Mutation (SNP) | VAF 92/707 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP2 | c.848T>C p.I283T | Missense Mutation (SNP) | VAF 50/500 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- NOD2 | c.1072G>T p.V358F | Missense Mutation (SNP) | VAF 122/1460 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- NPHS2 | c.1047C>A p.C349* | Nonsense Mutation (SNP) | VAF 107/690 reads (16%) | called by muse, mutect2, varscan2
- NR3C2 | c.2073G>T p.Q691H | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- NUP205 | c.3898G>T p.D1300Y | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- OR2S2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR51F2 | c.24dup p.A9Cfs*2 | Frame Shift Ins (INS) | VAF 27/257 reads (11%) | called by mutect2, pindel, varscan2
- OR5H1 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 64/876 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- OTOG | c.1756C>A p.Q586K | Missense Mutation (SNP) | VAF 52/446 reads (12%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PAPSS1 | c.1519dup p.C507Lfs*32 | Frame Shift Ins (INS) | VAF 29/226 reads (13%) | called by mutect2, pindel, varscan2
- PCDHB6 | c.1593del p.T532Qfs*8 | Frame Shift Del (DEL) | VAF 62/546 reads (11%) | called by mutect2, varscan2
- PNLIP | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRLR | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- PTPRD | c.1176G>T p.R392S | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); called by muse, mutect2
- SIGLEC10 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.425); called by muse, mutect2
- SLC2A12 | c.372G>C p.L124F | Missense Mutation (SNP) | VAF 53/344 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- SLCO6A1 | c.2109T>A p.D703E | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SSBP3 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TECTA | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2
- TRPA1 | c.2483C>A p.A828D | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- UNC5A | c.1597C>A p.L533M | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- YEATS2 | c.1961del p.P654Qfs*10 | Frame Shift Del (DEL) | VAF 19/182 reads (10%) | called by mutect2, pindel, varscan2
- YLPM1 | c.5431G>T p.E1811* | Nonsense Mutation (SNP) | VAF 45/398 reads (11%) | called by muse, mutect2, varscan2
- ZNF594 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- ZNF805 | c.1616A>T p.Y539F | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ZNF84 | c.1615G>C p.G539R | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADGRF1 | c.420C>G p.L140= | Silent (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2, varscan2
- ATP10B | c.814C>A p.R272= | Silent (SNP) | VAF 69/579 reads (12%) | catalogued as COSV58779084; called by muse, mutect2, varscan2
- CEACAM18 | c.234G>T p.P78= | Silent (SNP) | VAF 68/494 reads (14%) | catalogued as rs762385365, COSV67283316; called by muse, mutect2, varscan2
- CSMD3 | c.6528T>A p.T2176= (on ENST00000297405 / NM_001363185.1; = p.T2072= on NM_052900.3) | Silent (SNP) | VAF 89/712 reads (13%) | called by muse, mutect2, varscan2
- MXRA5 | c.6510C>G p.A2170= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.570C>T p.P190= (on ENST00000259318 / NM_001136562.3; = p.P421= on NM_007203.5) | Silent (SNP) | VAF 35/268 reads (13%) | catalogued as COSV99394696; called by muse, mutect2, varscan2
- PCDHB8 | c.2256C>T p.Y752= | Silent (SNP) | VAF 38/261 reads (15%) | catalogued as rs534687157, COSV50753819; called by muse, mutect2, varscan2
- PGBD4 | c.210G>A p.G70= | Silent (SNP) | VAF 21/201 reads (10%) | called by muse, mutect2
- PIEZO2 | c.3961C>T p.L1321= | Silent (SNP) | VAF 107/689 reads (16%) | called by muse, mutect2, varscan2
- PIGZ | c.981G>A p.G327= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- SETX | c.4353A>G p.V1451= | Silent (SNP) | VAF 32/868 reads (4%) | catalogued as rs771367273; ClinVar: likely benign; called by muse, mutect2
- SIRPB1 | c.813C>A p.T271= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV99498410; called by muse, mutect2
- SLC28A1 | c.618C>A p.A206= | Silent (SNP) | VAF 38/291 reads (13%) | called by muse, mutect2, varscan2
- SNPH | c.762G>T p.R254= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- SNRPB | c.351G>T p.G117= | Silent (SNP) | VAF 43/274 reads (16%) | called by muse, mutect2, varscan2
- TPRX1 | c.951C>A p.V317= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- TTC13 | c.2034C>G p.P678= | Silent (SNP) | VAF 26/486 reads (5%) | catalogued as rs1029189554; called by muse, mutect2
- ZNF100 | c.741C>G p.T247= | Silent (SNP) | VAF 32/296 reads (11%) | called by muse, mutect2, varscan2
- ZNF648 | c.1413T>A p.T471= | Silent (SNP) | VAF 33/286 reads (12%) | called by muse, mutect2, varscan2
- AC104472.1 | n.502A>G | RNA (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- ADAM6 | n.998G>C | RNA (SNP) | VAF 30/232 reads (13%) | called by muse, mutect2, varscan2
- AGXT | c.847-266G>A | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- AHRR | c.709-148A>G | Intron (SNP) | VAF 29/239 reads (12%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822331 A>T | 5'Flank (SNP) | VAF 35/460 reads (8%) | called by muse, mutect2
- CLEC18C | c.125-59G>T | Intron (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- H2BP2 | chr1:143876201 C>A | 3'Flank (SNP) | VAF 86/1010 reads (9%) | called by muse, mutect2, varscan2
- MIR518C | n.84T>A | RNA (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- NRXN2 | c.*14C>A | 3'UTR (SNP) | VAF 6/58 reads (10%) | catalogued as COSV55452609; called by mutect2, varscan2
- OR10AB1P | n.1353C>T | RNA (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- RASGRP2 | c.73+14G>T | Intron (SNP) | VAF 34/406 reads (8%) | called by muse, mutect2
- RBFOX1 | c.351+152554C>A | Intron (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- RPS9 | c.407+113A>G | Intron (SNP) | VAF 19/356 reads (5%) | called by muse, mutect2
- TNS3 | chr7:47582450 G>A | 5'Flank (SNP) | VAF 16/414 reads (4%) | called by muse, mutect2
- ZNF720 | c.361+1330T>G | Intron (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
